Gene-level copy-number profile of tumor specimen TCGA-CI-6624-01C from TCGA case TCGA-CI-6624, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.2 years (19,419 days).
Specimen TCGA-CI-6624-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.3025547b-675d-4512-8f62-0c26d1a581bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CI-6624-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4b1193b-7d9a-43cd-ae23-bf26117b272b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,192; copy number 2: 22,816; copy number 3: 25,056; copy number 4: 4,839; copy number 5: 2,864; copy number 6: 1,779; copy number 7: 1,216; copy number 9: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CI-6624-01C-11D-1825-01): tumor purity 0.34, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,271 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:83,796,436–84,651,334, 7 genes, copy number 7 (within-gene range 5–7): AC079160.1, RNU6-774P, AC025538.1, AC104063.1, NKX6-1, RPL3P13, CDS1.
- chr4:84,687,725–84,688,000, 1 gene, copy number 7: RN7SL552P.
- chr13:42,842,414–114,337,626, 911 genes, copy number 7 (broad region; genes not listed).
- chr20:43,489,442–44,696,096, 35 genes, copy number 7 (within-gene range 5–7): L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1.
- chr20:47,656,348–55,075,140, 139 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:55,607,852–61,940,617, 122 genes, copy number 7 (broad region; genes not listed).
- chr20:61,953,546–61,953,662, 1 gene, copy number 7: MIR1257.
- chr20:63,520,765–64,313,132, 55 genes, copy number 9: PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 1,192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
